CMI case MBCProject_0375 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/5a6abb78-a586-405d-ae39-70e8acdde225

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (6 samples)
- Sample MBCProject_0375_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Samples MBCProject_0375_T1_A_RNA, MBCProject_0375_T1_A_WES, MBCProject_0375_T1_B_RNA, MBCProject_0375_T1_C_RNA, MBCProject_0375_T1_C_WES (5 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
